CCDI case PBBVSC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/853beacd-c865-4591-ae69-8330c513c24e

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.3 years (3,755 days).

Biospecimens (3 samples)
- Sample 0DIKJH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIKJP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIKK4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
